Gene-level copy-number profile of tumor specimen C3L-04082-01 (profiled together with C3L-04082-02, C3L-04082-03) from CPTAC case C3L-04082, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.1 years (25,245 days).
Specimen C3L-04082-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebf7c177-2ce5-49df-b965-6d019c865c13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04082-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ba223bff-bda2-4edd-8d3a-776798286ab7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 11,468; copy number 2: 43,421; copy number 3: 3,013; copy number 4: 18; copy number 5: 458.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,954,291–8,026,309, 4 genes: PARK7, Y_RNA, AL034417.4, ERRFI1.
- chr4:85,475,150–86,002,668, 2 genes (within-gene range 0–1): ARHGAP24, MIR4451.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–2): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:12,182,096–12,194,133, 1 gene (within-gene range 0–4): FAM86B1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr22:18,533,646–18,653,617, 8 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 458 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,709,478–26,143,305, 458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,464. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
